Surgical pathology report (de-identified scan), TCGA case TCGA-JW-A69B, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site BLN - Baylor, specimen TCGA-JW-A69B-01A (Primary Tumor).

[page 1 of 3]
Results

Surgical Pathology:
(note)

Hospital Number
Location

SURGICAL PATHOLOGY

Accession #:

Collected:

Received:

*ICD-O-3
Adenocarcinoma, endocervical type
8384/3
Site Cervix NOS
C53.9
JW 6/17/13*

PATHOLOGIC DIAGNOSIS

A. ENDOMETRIUM, BIOPSY:

- ADENOCARCINOMA FAVOR ENDOCERVICAL ORIGIN (SEE COMMENT)

B. CERVIX, BIOPSY:

- ADENOCARCINOMA FAVOR ENDOCERVICAL ORIGIN (SEE COMMENT)

C. CERVIX, BIOPSY:

- ADENOCARCINOMA FAVOR ENDOCERVICAL ORIGIN (SEE COMMENT)
- FRAGMENT OF SEVERELY DYSPLASTIC SQUAMOUS EPITHELIUM

Staff Pathologist

Comment

Sections of the endometrial and cervical biopsies show an invasive adenocarcinoma. Immunohistochemical stains are performed to differentiate the origin of the malignant glands, with the appropriate controls, as follows: p16 positive (strong, diffuse), and CEA positive (patchy); ER, and vimentin negative. The combined morphology and immunohistochemistry panel favor an endocervical origin. Clinical correlation is recommended.

Intradepartmental consultation with Dr. _____
the above diagnosis.

who agrees with

_____ was notified of the diagnosis on _____ at _____

Pertinent Clinical Information

Abnormal uterine bleeding and abnormal enlarged cervix.

Gross Description

Specimen Material: A- Endometrial biopsy; B- Cervical biopsy; C- Cervical biopsy.

The case is received in three parts labeled with the patient's name _____, medical record number and given accession number _____ and it is accompanied by a requisition form labeled with the same name and accession number.

Part A: Received in formalin labeled _____ is a 2.6 x 0.7 x 0.3 cm

[page 2 of 3]
aggregate of pink to dark-brown mucoid tissue. The specimen is submitted in toto following filtration in cassette A.

Part B: Received in formalin labeled "BIOPSY CERVIX MASS" are 0.3 x 0.3 x 0.2 and 0.3 x 0.4 x 0.2 and 0.3 x 0.2 x 0.2 cm white-tan, firm, irregular tissue fragments as well as aggregates of tan to dark-brown tissues measuring 1.4 x 0.4 x 0.3 cm. The specimen is submitted in toto following filtration in cassette B.

Part C: Received in formalin labeled "BIOPSY CERVICAL MASS" is a 1.5 x 0.6 x 0.2 cm aggregate of white-tan, firm, irregular tissue. The specimen is submitted in toto following filtration in cassette C.

Pathology Resident
Microscopic Description
A-C: Performed.

This case was reviewed by the staff pathologist listed below.

This Immunohistochemistry test(s) was developed and its performance characteristics determined by the _____ and/or affiliated institution. It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

Pathology Resident
Electronically Signed Out

Staff Pathologist

[page 3 of 3]
Order**SURGICAL PATHOLOGY****No Administrations
Recorded**

Order Date/Time

Release Date/Time
None

Start Date/Time

End Date/Time
NoneFrequency
NoneDuration
NonePriority
RoutineOrder Class
NormalOrdering Quantity
1

Collection Date

Collection Time

Resulting Agency

Ordering User
Lab In Interface

Authorizing Provider

Attending Provider(s)

There are no order-level documents.

**** None ****

Source: NCI Genomic Data Commons file c1e78a25-82a6-4c4b-8724-8f5e0df075ca (TCGA-JW-A69B.5C2BA942-7F36-496E-AB8F-0EF8A5DE9669.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).